Somatic mutation profile of tumor specimen 0DT9NQ from CCDI case PBCJJJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,331 days).
Specimen 0DT9NQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2feead7-b2e5-4d9d-b4be-be7608e20855.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9ND (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82d52d1a-8df8-408c-9660-259d7ce59a5a

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTM1 | c.678+1G>A p.X226_splice | Splice Site (SNP) | VAF 168/208 reads (81%) | catalogued as rs587783849, CD972893, CS991459; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNND2 | c.3256del p.R1086Gfs*28 | Frame Shift Del (DEL) | VAF 166/536 reads (31%) | called by mutect2, pindel, varscan2
- FAM13B | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- H1-4 | c.384_404del p.A132_P138del | In Frame Del (DEL) | VAF 150/365 reads (41%) | called by mutect2, pindel, varscan2
- MAMSTR | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- RHPN1 | c.176+1G>A p.X59_splice | Splice Site (SNP) | VAF 36/336 reads (11%) | called by muse, mutect2, varscan2
- TRIM33 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 144/392 reads (37%) | called by muse, mutect2, varscan2
- CDYL | c.1434C>T p.F478= (on ENST00000328908 / NM_001368125.1; = p.F424= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 179/438 reads (41%) | catalogued as rs372837191, COSV59358215; called by muse, mutect2, varscan2
- GHR | c.333C>T p.S111= | Silent (SNP) | VAF 15/558 reads (3%) | catalogued as rs1242614937; called by muse, mutect2
- PCNX3 | c.1134C>T p.L378= | Silent (SNP) | VAF 138/321 reads (43%) | catalogued as rs1191330315; called by muse, mutect2, varscan2
- SPG21 | c.684T>C p.S228= | Silent (SNP) | VAF 142/350 reads (41%) | called by muse, mutect2, varscan2
- ITFG2 | chr12:2812664 T>C | 5'Flank (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- NEIL1 | c.*1680C>T | 3'UTR (SNP) | VAF 12/231 reads (5%) | catalogued as rs1211434763; called by muse, mutect2
